Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A195, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A195-06A (Metastatic).

1ED-0-3

Melanoma; NOS 8720/3

12/14/10 lu

PATIENT HISTORY:

year old man with melanoma.
PRE-OP DIAGNOSIS: Left axillary mass.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Excision left axillary mass and left posterior trunk mass.

Site code: TRUNK, Soft tissue C49.6

FINAL DIAGNOSIS:

PART 1: SOFT TISSUE, LEFT AXILLARY, EXCISION-
METASTATIC MELANOMA INVOLVING LYMPH NODES WITH EXTRACAPSULAR SPREAD.

PART 2: SOFT TISSUE, LEFT POSTERIOR TRUNK, EXCISION -

- A. MALIGNANT MELANOMA INVOLVING SUBCUTANEOUS TISSUE AND LYMPH NODE WITH EXTRACAPSULAR SPREAD (see comment).
- B. FOREIGN BODY GIANT CELL REACTION AND ORGANIZING HEMATOMA (PREVIOUS SURGICAL SITE).

COMMENT:

The neoplasm is immunoreactive for S100, Tyrosinase and MelanA and is negative for pankeratin, supporting melanoma. The tumor may represent a metastasis or recurrence.

Source: NCI Genomic Data Commons file 3ecf34f9-2b9e-499d-9938-dd33aff833fc (TCGA-ER-A195.4F82982F-C63B-4038-9D89-8ABF41B328A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).